Somatic mutation profile of tumor specimen 0DNMAR from CCDI case PBCBJR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.1 years (399 days).
Specimen 0DNMAR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4385f44-4bb7-4fe8-8ee9-18b9e27189f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNMA1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96fddc4d-4e43-4c3d-a53c-10266619f6d5

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATL1 | c.634C>A p.L212M | Missense Mutation (SNP) | VAF 254/704 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, varscan2
- SNIP1 | c.777G>T p.W259C | Missense Mutation (SNP) | VAF 144/440 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); called by muse, varscan2
